Gene-level copy-number profile of tumor specimen C3N-01495-01 (profiled together with C3N-01495-02) from CPTAC case C3N-01495, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS.
Specimen C3N-01495-01: Sample type: Primary Tumor; Tissue type: Tumor; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 41fca2e2-a822-42de-a261-23b3bfb46e37.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01495-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/f66fef25-258d-401c-9ccf-ff4600d880f6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 4,589; copy number 2: 40,389; copy number 3: 6,081; copy number 4: 7,322; copy number 5: 11; copy number 7: 5.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:112,827,213–112,867,582, 1 gene (within-gene range 0–1): AC008575.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–31,109, 5 genes, copy number 7: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2.
- chr4:69,280,475–69,358,177, 3 genes, copy number 5: UGT2B28, AC114786.3, AC114786.2.
- chr4:69,408,828–69,423,164, 1 gene, copy number 5 (within-gene range 3–5): UGT2B24P.
- chr7:38,269,491–38,300,322, 6 genes, copy number 5 (within-gene range 4–5): TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.
- chr13:49,232,874–49,234,399, 1 gene, copy number 5: AL137000.1.

Autosomal genes at a single copy (total copy number 1): 2,245. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
